Gene-level copy-number profile of tumor specimen TCGA-DU-6407-02A from TCGA case TCGA-DU-6407, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 35.6 years (13,021 days).
Specimen TCGA-DU-6407-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.061d0d69-94b7-4c97-b5ce-757caa5f328c.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DU-6407-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 393 have no estimate.
https://portal.gdc.cancer.gov/files/070d1fde-6b99-4745-872d-9db3367ad533

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 545; copy number 1: 5,522; copy number 2: 47,532; copy number 3: 6,318; copy number 4: 294; copy number 5: 10; copy number 6: 9.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–2): RSRP1.
- chr1:25,266,102–25,337,465, 4 genes: AL031432.2, RHD, SDHDP6, AL928711.1.
- chr6:30,516,266–30,557,174, 2 genes: LINC02569, GNL1.
- chr9:60,914,407–61,662,690, 17 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, BX005040.4, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr22:32,188,400–32,188,487, 1 gene: AL008723.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:53,519,527–53,637,009, 5 genes, copy number 6 (within-gene range 2–6): ZNF331, AC011487.2, OSTCP3, RN7SL317P, DPRX.
- chr19:55,891,699–56,185,775, 10 genes, copy number 5 (within-gene range 2–5): NLRP13, NLRP8, NLRP5, LINC01864, ZNF787, Y_RNA, AC024580.2, ZNF444, AC024580.1, GALP.

Autosomal genes at a single copy (total copy number 1): 4,540. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
